Somatic mutation profile of tumor specimen TCGA-D9-A4Z6-06A (aliquot TCGA-D9-A4Z6-06A-12D-A25O-08) from TCGA case TCGA-D9-A4Z6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.4 years (20,236 days).
Specimen TCGA-D9-A4Z6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49e64060-a618-4f7e-8efd-91d91e7767a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A4Z6-10A (Blood Derived Normal), aliquot TCGA-D9-A4Z6-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7c67d43-f887-4eda-9bcb-d1f6a1e898e1

The open-access MAF lists 325 somatic variants for this specimen: 226 protein-altering or splice-affecting, 92 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 92, Nonsense Mutation 9, Splice Site 6, Intron 4, Splice Region 2, Frame Shift Del 2, RNA 2, Nonstop Mutation 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908803, CM930101, COSV50040652; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.43383G>A p.W14461* (on ENST00000591111; = p.W7037* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as rs771672410, COSV60303196; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.7309C>A p.Q2437K (on ENST00000272895 / NM_173076.3; = p.Q2119K on NM_015657.3) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as COSV55973326; called by muse, mutect2
- ABCC12 | c.2332A>T p.T778S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV60917745; called by muse, mutect2, varscan2
- ABCC4 | c.2695C>T p.P899S | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs780945816, COSV65317710; called by muse, mutect2, varscan2
- ABHD4 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as rs763873898, COSV53530568; called by muse, mutect2, varscan2
- AC011455.2 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55501455; called by muse, mutect2, varscan2
- ADGRF5 | c.3428C>T p.S1143L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1327922158, COSV51939297; called by muse, mutect2, varscan2
- ADGRG4 | c.3631G>A p.D1211N | Missense Mutation (SNP) | VAF 70/88 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54965445; called by muse, mutect2, varscan2
- AGFG2 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53544829; called by muse, mutect2, varscan2
- AKR1B10 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV62056504; called by muse, mutect2, varscan2
- ALDH1A1 | c.1167T>G p.N389K | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV52793916; called by muse, mutect2, varscan2
- AMOT | c.2399C>T p.S800F (on ENST00000371959 / NM_001113490.1; = p.S391F on NM_133265.3) | Missense Mutation (SNP) | VAF 64/88 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV59067589; called by muse, mutect2, varscan2
- ANKRD11 | c.5254C>T p.P1752S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777776761, COSV56370386; called by muse, mutect2, varscan2
- ANKRD44 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV56564470; called by muse, mutect2, varscan2
- ANKS1B | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs1180061246, COSV61372862; called by muse, mutect2, varscan2
- AQP10 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61476039; called by muse, mutect2, varscan2
- AQP9 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs367676440, COSV54968868; called by muse, mutect2, varscan2
- ARID3C | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1428849160, COSV52408877; called by muse, mutect2, varscan2
- BCL9 | c.2168A>C p.N723T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV52349501; called by muse, mutect2, varscan2
- BRAF | c.2296C>T p.R766C (on ENST00000288602 / NM_001374244.1; = p.R726C on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56224489; called by muse, mutect2, varscan2
- CACNA1E | c.1959C>T p.I653= | Splice Region (SNP) | VAF 33/72 reads (46%) | catalogued as rs757203952, COSV62415427; called by muse, mutect2, varscan2
- CCDC54 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs1427679891, COSV53759195, COSV53759745; called by muse, mutect2, varscan2
- CCIN | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58725506; called by muse, mutect2, varscan2
- CCL8 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.458); catalogued as COSV67013971; called by muse, mutect2, varscan2
- CD163L1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV58023548; called by muse, mutect2, varscan2
- CD34 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV60414826; called by muse, mutect2, varscan2
- CFHR3 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.636); catalogued as COSV66403208; called by muse, mutect2, varscan2
- CHAC2 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs369539876, COSV54858669; called by muse, mutect2, varscan2
- CHODL | c.362G>A p.W121* | Nonsense Mutation (SNP) | VAF 42/80 reads (53%) | catalogued as COSV54735066; called by muse, mutect2, varscan2
- CLCA1 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52330729; called by muse, mutect2, varscan2
- CLU | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs528753124, COSV57066568; called by muse, mutect2, varscan2
- COL12A1 | c.868A>C p.T290P | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV59406312; called by muse, mutect2, varscan2
- COL16A1 | c.3503G>A p.G1168E | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54712977; called by muse, mutect2, varscan2
- COL4A1 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as COSV65431214; called by muse, mutect2, varscan2
- COL6A3 | c.8575C>T p.P2859S | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV55081030; called by muse, mutect2, varscan2
- COL6A3 | c.3828C>A p.F1276L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV55106590; called by muse, mutect2, varscan2
- CPAMD8 | c.982G>A p.G328R (on ENST00000651564; = p.G281R on NM_015692.5) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52239260; called by muse, mutect2, varscan2
- CYP3A4 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV60503946; called by muse, mutect2, varscan2
- CYP3A5 | c.166-1G>A p.X56_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | catalogued as COSV56122804, COSV56123474; called by muse, mutect2, varscan2
- CYP4F12 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.383); catalogued as rs751637116, COSV61176272; called by muse, mutect2, varscan2
- CYYR1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV54837113; called by muse, mutect2, varscan2
- D2HGDH | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58323210; called by muse, mutect2, varscan2
- DHX36 | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100273650; called by mutect2, varscan2
- DHX36 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100273652; called by muse, mutect2, varscan2
- DNAH11 | c.11212G>A p.V3738M | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs777903360, COSV60977878; called by muse, mutect2, varscan2
- DNAH3 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV54531454; called by muse, mutect2, varscan2
- DNAJC10 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.577); catalogued as COSV51145783; called by muse, mutect2, varscan2
- DNTTIP2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as COSV63284547; called by muse, mutect2, varscan2
- DOK6 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV66926338; called by muse, mutect2, varscan2
- DOP1B | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV67695748; called by muse, mutect2, varscan2
- DPYSL5 | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56515784; called by muse, mutect2, varscan2
- DSG2 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV55198430, COSV99853037; called by muse, varscan2
- DYNAP | c.422C>T p.S141L (on ENST00000321600; = p.S115L on NM_173629.3) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs760155446, COSV58666818; called by muse, mutect2, varscan2
- EHMT2 | c.2684C>T p.S895F | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64997856; called by muse, mutect2, varscan2
- EIF3A | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64963109; called by muse, mutect2, varscan2
- EIF4G1 | c.4297C>T p.P1433S (on ENST00000346169 / NM_198241.3; = p.P1238S on NM_004953.5) | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0.014); catalogued as rs147696097; called by muse, mutect2, varscan2
- EPB41L4B | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV63124270; called by muse, mutect2, varscan2
- FAM135B | c.1206G>A p.W402* | Nonsense Mutation (SNP) | VAF 37/100 reads (37%) | catalogued as COSV52749959; called by muse, mutect2, varscan2
- FAM177B | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV62601769; called by muse, mutect2, varscan2
- FAM184A | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as rs141308759, COSV58851670; called by muse, mutect2, varscan2
- FAM83C | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV65584267; called by muse, mutect2, varscan2
- FAT4 | c.7963G>A p.E2655K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.993); catalogued as rs556536853, COSV58679417; called by muse, mutect2, varscan2
- FCGBP | c.6842G>A p.G2281D | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs1468561979; called by muse, mutect2, varscan2
- FLG2 | c.1685G>A p.R562K | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.364); catalogued as COSV66171920, COSV66172428; called by muse, mutect2, varscan2
- FLRT3 | c.1091T>C p.I364T | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1239938852, COSV54044447; called by muse, mutect2, varscan2
- FRYL | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51960320; called by muse, mutect2, varscan2
- FUT2 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.174); catalogued as COSV67179707; called by muse, mutect2, varscan2
- GABRA2 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs138677063, COSV62914309, COSV62919289; called by muse, mutect2, varscan2
- GPR141 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57733863; called by muse, mutect2, varscan2
- GRHL1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as COSV100257888; called by muse, mutect2, varscan2
- GRIN2B | c.1147T>C p.S383P | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.313); catalogued as COSV74207529; called by muse, mutect2, varscan2
- GSDMC | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV52698697; called by muse, mutect2
- GTF3C1 | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV62244497; called by muse, mutect2, varscan2
- HDAC9 | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1273831560, COSV67783873, COSV67788218; called by muse, mutect2
- HERC2 | c.3811C>T p.R1271W | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763375687, COSV55346911; called by muse, mutect2, varscan2
- IFT172 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53130951; called by muse, mutect2, varscan2
- IKZF2 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV59580457; called by muse, mutect2, varscan2
- IL37 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54490299; called by muse, mutect2, varscan2
- IQCE | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746212612, COSV58081622; called by muse, mutect2, varscan2
- IQCN | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV66577352; called by muse, mutect2, varscan2
- IQGAP3 | c.4282C>T p.H1428Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs775613036, COSV63254256; called by muse, mutect2, varscan2
- IRX4 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs756079054, COSV51474636; called by muse, mutect2, varscan2
- ITGB6 | c.142-1G>A p.X48_splice | Splice Site (SNP) | VAF 31/76 reads (41%) | catalogued as COSV51798136; called by muse, mutect2, varscan2
- ITIH3 | c.1617G>A p.M539I | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV69650025; called by muse, mutect2, varscan2
- ITK | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV68435461; called by muse, mutect2, varscan2
- KCNH5 | c.2409G>A p.M803I | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV59775293; called by muse, mutect2, varscan2
- KCNJ15 | c.1057_1059del p.E353del | In Frame Del (DEL) | VAF 21/52 reads (40%) | catalogued as rs1569023234; called by pindel, varscan2
- KCNJ3 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.054); catalogued as rs868672401, COSV54530586, COSV54543402; called by muse, mutect2, varscan2
- KCNN3 | c.1550C>A p.S517Y (on ENST00000618040 / NM_001204087.1; = p.S502Y on NM_002249.6) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55225532; called by muse, mutect2, varscan2
- KCNQ3 | c.1566C>T p.V522= | Splice Region (SNP) | VAF 20/69 reads (29%) | catalogued as COSV66480558; called by muse, mutect2, varscan2
- KCNV1 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52088791; called by muse, mutect2, varscan2
- KIAA1217 | c.3082+1G>A p.X1028_splice | Splice Site (SNP) | VAF 3/34 reads (9%) | catalogued as COSV56822538; called by muse, mutect2
- KIF26B | c.6080G>A p.R2027K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV63650590; called by muse, mutect2, varscan2
- KIR2DL3 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs771803423; called by muse, mutect2, varscan2
- KIR2DL3 | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1319460528; called by muse, mutect2, varscan2
- KLK15 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as COSV56828404; called by muse, mutect2, varscan2
- KRT3 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV58814682; called by muse, mutect2, varscan2
- LAMB4 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV52719096; called by muse, mutect2, varscan2
- LAMC3 | c.3122C>T p.S1041F | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV63094922; called by muse, mutect2, varscan2
- LCN2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs749080993, COSV52981780, COSV99478201; called by muse, varscan2
- LENG1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as rs754236725, COSV55363538; called by muse, mutect2, varscan2
- LRP1B | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868474587, COSV67244499; called by muse, mutect2, varscan2
- LRPPRC | c.3512C>T p.S1171F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs925087564, COSV53242641; called by muse, mutect2, varscan2
- MAP3K20 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100919515; called by muse, mutect2, varscan2
- MARF1 | c.2768C>T p.T923M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs368220990, COSV60023592; called by muse, mutect2, varscan2
- MASP1 | c.1913G>A p.G638E | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs867948727, COSV61830451; called by muse, mutect2, varscan2
- MCTP2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1425029188, COSV59142077; called by muse, mutect2, varscan2
- MEMO1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs775618103, COSV54451903; called by muse, mutect2, varscan2
- MERTK | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV54935021; called by muse, mutect2, varscan2
- MROH2B | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV68188823; called by muse, mutect2, varscan2
- MS4A15 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.276); catalogued as COSV100558890; called by muse, mutect2, varscan2
- MS4A15 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV100558892; called by muse, mutect2, varscan2
- MSH5 | c.2342G>A p.G781E | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV65174070; called by muse, mutect2, varscan2
- MYF6 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57353087; called by muse, mutect2, varscan2
- MYLK3 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV67365585, COSV67366485; called by muse, mutect2
- MYLK3 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as COSV67366496; called by muse, mutect2
- MYO7B | c.5260T>C p.F1754L | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67351424; called by muse, mutect2, varscan2
- MYOCD | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58497540; called by muse, mutect2, varscan2
- MYOM2 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50763818; called by muse, mutect2, varscan2
- NCAM1 | c.2518G>A p.E840K (on ENST00000316851 / NM_181351.5; = p.E830K on NM_000615.7) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1555126347, COSV57523681; called by muse, mutect2, varscan2
- NEXMIF | c.2521A>T p.N841Y | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.34); PolyPhen benign (0.116); catalogued as COSV50091420; called by muse, mutect2, varscan2
- NLRP1 | c.3250G>A p.G1084R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52577346, COSV52581498; called by muse, mutect2, varscan2
- NLRP4 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56712975; called by muse, mutect2, varscan2
- NLRP4 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56708963; called by muse, mutect2, varscan2
- NLRP5 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs768523862, COSV66767069; called by muse, mutect2, varscan2
- NME7 | c.1131G>T p.*377Yext*5 | Nonstop Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV63170433; called by muse, mutect2, varscan2
- NPR1 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.107); catalogued as COSV64143321; called by muse, mutect2, varscan2
- NSMAF | c.1216+1G>C p.X406_splice | Splice Site (SNP) | VAF 14/33 reads (42%) | catalogued as COSV50699369; called by muse, mutect2, varscan2
- NTRK2 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52879641; called by muse, mutect2, varscan2
- NUDT1 | c.326T>C p.F109S (on ENST00000397048 / NM_198952.1; = p.F86S on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56129820; called by muse, mutect2, varscan2
- OAS1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs771818638, COSV99177085; called by muse, mutect2, varscan2
- OLFML2B | c.1411G>A p.G471R | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as rs752528033, COSV54199939; called by muse, mutect2, varscan2
- OPLAH | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70679162; called by muse, mutect2, varscan2
- OR14A16 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as COSV62926091, COSV62926585, COSV62927398; called by muse, mutect2, varscan2
- OR4A5 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.173); catalogued as COSV60523427; called by muse, mutect2, varscan2
- OR6M1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1204357947, COSV58434762; called by muse, mutect2, varscan2
- PCDHB15 | c.1774G>A p.V592M | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99178980; called by muse, mutect2, varscan2
- PCDHB5 | c.1067C>A p.P356Q | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV50648019, COSV50667179; called by muse, mutect2, varscan2
- PKD1L1 | c.7699G>A p.G2567R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51844773; called by muse, mutect2, varscan2
- PKD1L1 | c.5372C>T p.S1791F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV56965672; called by muse, mutect2, varscan2
- PKD2L2 | c.1101T>A p.Y367* | Nonsense Mutation (SNP) | VAF 10/12 reads (83%) | catalogued as COSV51801082; called by muse, mutect2, varscan2
- PLD5 | c.880G>A p.E294K (on ENST00000442594; = p.E232K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV59165350; called by muse, mutect2, varscan2
- PNLIP | c.1169+2T>G p.X390_splice | Splice Site (SNP) | VAF 8/12 reads (67%) | catalogued as COSV65041875; called by muse, mutect2
- POM121L12 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.637); catalogued as COSV68694213; called by muse, mutect2, varscan2
- PRSS16 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57916722; called by muse, mutect2, varscan2
- PRX | c.2785T>G p.S929A | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as COSV52532937; called by muse, mutect2, varscan2
- PSG1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 113/295 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV54952666; called by muse, mutect2, varscan2
- PSME3IP1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV58430328; called by muse, mutect2, varscan2
- PSTPIP2 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs1336846399, COSV68958747; called by muse, mutect2, varscan2
- PTGER3 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60697079; called by muse, mutect2, varscan2
- PTPRB | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs724159874, COSV54239392; called by muse, mutect2, varscan2
- PTPRB | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54246170, COSV99719144; called by muse, mutect2, varscan2
- PTPRZ1 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as COSV66444474; called by muse, mutect2, varscan2
- PXDNL | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs1165654580, COSV62492637; called by muse, mutect2, varscan2
- PZP | c.3296G>A p.G1099E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54369012; called by muse, mutect2, varscan2
- RALGAPA2 | c.4781C>T p.P1594L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV52509513; called by muse, mutect2, varscan2
- RBMS2 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV56265624; called by muse, mutect2, varscan2
- REV3L | c.5779C>T p.L1927F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62622913; called by muse, mutect2, varscan2
- RGS22 | c.2247G>A p.M749I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs79298856, COSV62666844; called by muse, mutect2, varscan2
- RIMKLA | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.231); catalogued as COSV68909669; called by muse, mutect2, varscan2
- RIMS1 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV53480361; called by muse, mutect2, varscan2
- ROS1 | c.6689G>A p.R2230K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as COSV63853286, COSV63854679, COSV63859845; called by muse, mutect2, varscan2
- RP1 | c.37C>T p.H13Y | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV55125239; called by muse, mutect2, varscan2
- RTN4IP1 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV64805358; called by muse, mutect2, varscan2
- RUNDC1 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0.174); catalogued as rs746737893, COSV64512583; called by muse, mutect2, varscan2
- RUVBL2 | c.218T>A p.V73D | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55487012; called by muse, mutect2, varscan2
- SALL4 | c.2986C>T p.P996S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1468774027, COSV53854635; called by muse, mutect2, varscan2
- SAMD9 | c.3763C>T p.P1255S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1405843481, COSV66073972; called by muse, mutect2, varscan2
- SAMHD1 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV53431253; called by muse, mutect2, varscan2
- SCEL | c.1040G>A p.S347N (on ENST00000349847 / NM_144777.3; = p.S327N on NM_003843.4) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as COSV62994463; called by muse, mutect2, varscan2
- SCN9A | c.5937A>T p.K1979N (on ENST00000303354; = p.K1968N on NM_002977.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.022); catalogued as COSV57622132; called by muse, mutect2
- SDCCAG8 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as rs769004589, COSV59416613; called by muse, mutect2, varscan2
- SEC24B | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV54505688; called by muse, mutect2, varscan2
- SELENOP | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV62793863; called by muse, mutect2, varscan2
- SEMA3A | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as rs554613342, COSV54885826; called by muse, mutect2, varscan2
- SH3RF3 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58685389; called by muse, mutect2, varscan2
- SH3RF3 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV58694228; called by muse, mutect2, varscan2
- SHCBP1 | c.784T>A p.L262I | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.257); catalogued as COSV57650061; called by muse, mutect2, varscan2
- SLC10A2 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs200673810, COSV55361352; called by muse, mutect2, varscan2
- SLC10A2 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55361364; called by muse, mutect2, varscan2
- SLC12A6 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as rs200288608; called by muse, mutect2, varscan2
- SLC26A11 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV58340418; called by muse, mutect2, varscan2
- SLC35F6 | c.272T>A p.F91Y | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV60427101; called by muse, mutect2, varscan2
- SLC9C1 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.802); catalogued as COSV59892624; called by muse, mutect2, varscan2
- SLFN11 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57698484; called by muse, mutect2, varscan2
- SPRR4 | c.28C>G p.Q10E | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.05); catalogued as COSV60143228; called by muse, mutect2, varscan2
- STXBP5L | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV56510578; called by muse, mutect2, varscan2
- SULT2B1 | c.214+1G>A p.X72_splice (on ENST00000201586 / NM_177973.2; = p.X57_splice on NM_004605.2) | Splice Site (SNP) | VAF 37/83 reads (45%) | catalogued as COSV52378476; called by muse, mutect2, varscan2
- SVEP1 | c.2600G>A p.G867E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57046023; called by muse, mutect2
- TCEAL2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV61197688; called by muse, mutect2, varscan2
- TENM2 | c.1119G>A p.W373* (on ENST00000518659 / NM_001122679.2; = p.W182* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 23/33 reads (70%) | catalogued as COSV69139709; called by muse, mutect2, varscan2
- THSD7B | c.178G>T p.G60* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV55731740; called by muse, mutect2, varscan2
- TLL1 | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV50317290, COSV99286724; called by muse, mutect2, varscan2
- TNFAIP2 | c.717C>G p.F239L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs1330043373, COSV60695967; called by muse, mutect2, varscan2
- TP53BP1 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55508074; called by muse, mutect2, varscan2
- TPTE2 | c.1055G>A p.G352E (on ENST00000400230 / NM_199254.2; = p.G275E on NM_130785.3) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55026002; called by muse, mutect2, varscan2
- TRAF6 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV61923519; called by muse, mutect2, varscan2
- TRIM54 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs763773532, COSV56082677; called by muse, mutect2, varscan2
- TRPV6 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs748594853, COSV63890443; called by muse, mutect2, varscan2
- TSPEAR | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59978002; called by muse, mutect2, varscan2
- TTLL4 | c.3095C>T p.S1032F | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV51439059; called by muse, mutect2, varscan2
- TTN | c.10235G>A p.G3412E (on ENST00000591111; = p.G3366E on NM_003319.4) | Missense Mutation (SNP) | VAF 27/58 reads (47%) | PolyPhen probably damaging (1); catalogued as COSV100621289, COSV60303237; called by muse, mutect2, varscan2
- TYW1 | c.939T>G p.D313E | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62755779; called by muse, mutect2, varscan2
- USH2A | c.7210C>T p.P2404S | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56425816; called by muse, mutect2, varscan2
- VAV1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58379535; called by muse, mutect2, varscan2
- VPS13A | c.6349C>T p.L2117F | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62437707; called by muse, mutect2, varscan2
- VWF | c.8134C>T p.P2712S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as COSV54613290, COSV54613852; called by muse, mutect2, varscan2
- XIRP2 | c.4527A>C p.K1509N (on ENST00000628543; = p.K1684N on NM_152381.6) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV54730443; called by muse, mutect2, varscan2
- ZBTB32 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs370025737; called by muse, mutect2, varscan2
- ZDBF2 | c.1966C>T p.L656F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV100984832, COSV65629567; called by muse, mutect2, varscan2
- ZFHX4 | c.5821G>A p.E1941K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs544904221, COSV51441830; called by muse, mutect2, varscan2
- ZFPM2 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765404652, COSV65873778; called by muse, mutect2, varscan2
- ZNF275 | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64704875; called by muse, mutect2, varscan2
- ZNF334 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs779948503, COSV61619946; called by muse, mutect2, varscan2
- ZNF470 | c.1235T>C p.L412P | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1173902425, COSV57970516; called by muse, mutect2, varscan2
- ZNF665 | c.164T>C p.L55P (on ENST00000600412; = p.L120P on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV67217241; called by muse, mutect2, varscan2
- ZNF677 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs764153868, COSV61719732; called by muse, mutect2, varscan2
- ZNF804A | c.3532C>T p.H1178Y | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1460609576, COSV56455828; called by muse, mutect2, varscan2
- ZNF831 | c.3160T>A p.S1054T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV100926069; called by muse, mutect2, varscan2
- APC | c.893_896del p.H298Lfs*6 | Frame Shift Del (DEL) | VAF 14/22 reads (64%) | called by mutect2, pindel, varscan2
- ARMCX2 | c.1760_1763del p.N587Ifs*26 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- CWC25 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- GAGE2A | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 144/1834 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2
- HYDIN | c.5672C>T p.P1891L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ABCC11 | c.942C>T p.F314= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV62325550; called by muse, mutect2, varscan2
- ABCC12 | c.1362G>A p.K454= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV60911926, COSV60913332; called by muse, mutect2, varscan2
- ACACB | c.5905C>T p.L1969= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV58144755; called by muse, mutect2, varscan2
- AIFM1 | c.216T>C p.I72= | Silent (SNP) | VAF 64/77 reads (83%) | catalogued as COSV54857449; called by muse, mutect2, varscan2
- AP3D1 | c.1644C>T p.A548= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs776887277, COSV61432539; called by muse, mutect2, varscan2
- ATP2B2 | c.3072C>T p.I1024= (on ENST00000352432; = p.I990= on NM_001683.5) | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs868865508, COSV59494235; called by muse, mutect2, varscan2
- AURKA | c.594T>G p.G198= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV57170001; called by muse, mutect2, varscan2
- BRAF | c.2295C>T p.H765= (on ENST00000288602 / NM_001374244.1; = p.H725= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 56/141 reads (40%) | catalogued as COSV56250212, COSV99962741; called by muse, mutect2, varscan2
- BTBD11 | c.2916C>T p.I972= (on ENST00000280758 / NM_001018072.2; = p.I509= on NM_001017523.2) | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV55035730, COSV99776332; called by muse, mutect2, varscan2
- BTN3A1 | c.1341C>A p.P447= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV50025350, COSV99176338; called by muse, mutect2, varscan2
- CCDC87 | c.1144C>T p.L382= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV59580425; called by muse, mutect2, varscan2
- CD200R1 | c.232C>T p.L78= (on ENST00000471858 / NM_170780.3; = p.L101= on NM_138806.4) | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV55603272; called by muse, mutect2, varscan2
- CDH8 | c.1629G>A p.P543= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs980808256, COSV54856948; called by muse, mutect2, varscan2
- CFAP61 | c.2142G>A p.R714= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV55619190; called by muse, mutect2, varscan2
- CFHR1 | c.426C>T p.S142= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV57628887; called by muse, mutect2, varscan2
- CNTNAP5 | c.1101C>T p.P367= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV70499855, COSV70509030; called by muse, mutect2, varscan2
- CPNE9 | c.1359C>T p.P453= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV56069702; called by muse, mutect2
- CXCR1 | c.957C>T p.I319= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV55282546; called by muse, mutect2, varscan2
- DSCAM | c.4603C>T p.L1535= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV68034872; called by muse, mutect2, varscan2
- E4F1 | c.831C>T p.I277= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as COSV57040928, COSV57041086; called by muse, mutect2, varscan2
- FABP2 | c.30C>T p.D10= | Silent (SNP) | VAF 42/73 reads (58%) | catalogued as COSV56789238; called by muse, mutect2, varscan2
- FMN2 | c.4053G>A p.T1351= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as rs992801291, COSV60431286; called by muse, mutect2, varscan2
- GALNT17 | c.447G>A p.K149= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV61186992; called by muse, mutect2, varscan2
- GDPD5 | c.816C>T p.F272= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV61129938; called by muse, mutect2, varscan2
- GGA3 | c.855C>T p.N285= (on ENST00000537686 / NM_138619.4; = p.N252= on NM_014001.5) | Silent (SNP) | VAF 56/80 reads (70%) | catalogued as COSV55458789; called by muse, mutect2, varscan2
- GRHL1 | c.9G>A p.Q3= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs773457452, COSV100257883; called by muse, mutect2, varscan2
- GUCY1A1 | c.571C>T p.L191= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs1387174278, COSV56654569, COSV56655811; called by muse, mutect2, varscan2
- HAUS4 | c.810C>T p.V270= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV52828126; called by muse, mutect2, varscan2
- HCAR2 | c.247C>T p.L83= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV61025719; called by muse, mutect2, varscan2
- HMCN1 | c.4506A>G p.E1502= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV54935877; called by muse, mutect2, varscan2
- HPD | c.351C>T p.I117= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV56643523; called by muse, mutect2, varscan2
- IFNA16 | c.432G>A p.R144= | Silent (SNP) | VAF 77/124 reads (62%) | catalogued as rs1159411560, COSV66509823; called by muse, mutect2, varscan2
- IGFN1 | c.2325C>T p.I775= (on ENST00000295591 / NM_001367841.1; = p.I3232= on NM_001164586.2) | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV55177789; called by muse, mutect2, varscan2
- INO80 | c.4548C>T p.S1516= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV62741777; called by muse, mutect2, varscan2
- INPP5K | c.210C>T p.D70= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV57442416; called by muse, mutect2, varscan2
- IQCG | c.627C>T p.F209= | Silent (SNP) | VAF 31/48 reads (65%) | catalogued as COSV54561940; called by muse, mutect2, varscan2
- JAK2 | c.3102C>T p.A1034= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV101074389; called by muse, mutect2, varscan2
- KCNJ4 | c.858C>T p.I286= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs757723128, COSV57857452; called by muse, mutect2, varscan2
- KIF1C | c.894C>T p.I298= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as rs1377382628, COSV57903718; called by muse, mutect2, varscan2
- LENG1 | c.435C>T p.A145= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV99651968; called by muse, mutect2, varscan2
- MAGEC3 | c.1494C>T p.F498= | Silent (SNP) | VAF 36/51 reads (71%) | catalogued as rs1233995692, COSV53575710, COSV53577836; called by muse, mutect2, varscan2
- MAPT | c.1146C>T p.I382= (on ENST00000262410 / NM_001377265.1; = p.I307= on NM_016835.4) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV52246654; called by muse, mutect2
- MUC16 | c.26139C>T p.I8713= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV67477561; called by muse, mutect2, varscan2
- MUC16 | c.20100C>T p.S6700= | Silent (SNP) | VAF 63/150 reads (42%) | catalogued as rs777092040, COSV67489562; called by muse, mutect2, varscan2
- MUC16 | c.8577C>T p.L2859= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV67473576; called by muse, mutect2, varscan2
- MYF5 | c.753C>T p.I251= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV57354454, COSV99953055; called by muse, mutect2, varscan2
- MYO5B | c.1191G>A p.V397= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV53229206, COSV99543556; called by muse, mutect2, varscan2
- NPC1L1 | c.1311C>T p.D437= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs770179905, COSV56929696; called by muse, mutect2, varscan2
- OBSCN | c.17691C>T p.I5897= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV52821985; called by muse, mutect2, varscan2
- OR10A4 | c.702G>C p.G234= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as COSV65842412; called by muse, mutect2, varscan2
- OR10H2 | c.231C>T p.I77= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV59945324; called by muse, mutect2
- OR1C1 | c.684C>T p.I228= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV101376233, COSV68716308; called by muse, mutect2, varscan2
- OR1E2 | c.753C>T p.G251= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV50266156; called by muse, mutect2, varscan2
- OR5H6 | c.747G>A p.G249= (on ENST00000642105; = p.G233= on NM_001005479.2) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs146320551, COSV67351216; called by muse, mutect2, varscan2
- OR7G3 | c.123G>A p.G41= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV59640249; called by muse, mutect2, varscan2
- PEG3 | c.195C>T p.I65= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV55645412; called by muse, mutect2, varscan2
- PID1 | c.540C>T p.F180= (on ENST00000354069 / NM_001330156.1; = p.F178= on NM_017933.5) | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs749402709, COSV62472386; called by muse, mutect2, varscan2
- PIK3R5 | c.1242C>T p.H414= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs139885994; called by muse, mutect2, varscan2
- PLAG1 | c.924C>T p.I308= | Silent (SNP) | VAF 53/132 reads (40%) | catalogued as COSV57614494; called by muse, mutect2, varscan2
- PLCB2 | c.2202G>A p.K734= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV53037516; called by muse, mutect2, varscan2
- PMFBP1 | c.1038C>T p.I346= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1452457212, COSV52831043; called by muse, mutect2, varscan2
- POLR2A | c.4620C>T p.T1540= | Silent (SNP) | VAF 39/119 reads (33%) | called by muse, mutect2, varscan2
- PRAMEF14 | c.789C>T p.F263= | Silent (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- RIOX2 | c.324G>A p.G108= | Silent (SNP) | VAF 88/243 reads (36%) | catalogued as COSV57724826; called by muse, mutect2, varscan2
- RND1 | c.510C>T p.F170= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV59046035; called by muse, mutect2, varscan2
- ROCK1 | c.744C>T p.S248= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV67699028; called by muse, mutect2, varscan2
- RTEL1 | c.2856C>T p.F952= | Silent (SNP) | VAF 47/109 reads (43%) | catalogued as rs1041575386, COSV58900681; called by muse, mutect2, varscan2
- SCN5A | c.4809C>T p.I1603= (on ENST00000333535 / NM_198056.3; = p.I1602= on NM_000335.5) | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as rs769709544, COSV61124390; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEPTIN4 | c.1470G>A p.E490= | Silent (SNP) | VAF 128/310 reads (41%) | catalogued as COSV58728952; called by muse, mutect2, varscan2
- SIN3A | c.1923C>T p.S641= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs1354050046, COSV64584744; called by muse, mutect2, varscan2
- SLC26A8 | c.582C>T p.S194= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV62887426; called by muse, mutect2, varscan2
- SLC2A9 | c.1140G>A p.R380= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV53327574; called by muse, mutect2, varscan2
- SLC36A2 | c.468C>T p.I156= | Silent (SNP) | VAF 37/55 reads (67%) | catalogued as COSV58864885; called by muse, mutect2, varscan2
- SLC52A3 | c.1122G>A p.G374= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs755616826, COSV54079070; called by muse, mutect2, varscan2
- STAB2 | c.942C>T p.F314= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs144975292, COSV66337677; called by muse, mutect2, varscan2
- TAF7 | c.831G>A p.L277= | Silent (SNP) | VAF 38/53 reads (72%) | catalogued as rs769047000, COSV57664868, COSV57666112; called by muse, mutect2, varscan2
- TBC1D22A | c.183C>T p.F61= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV61445111; called by muse, mutect2, varscan2
- TBX18 | c.1368C>T p.S456= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs974623808, COSV63738078; ClinVar: likely benign; called by muse, mutect2, varscan2
- TIMM44 | c.606G>A p.R202= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV54494341; called by muse, mutect2, varscan2
- TMEM132B | c.840G>A p.E280= | Silent (SNP) | VAF 60/155 reads (39%) | catalogued as COSV54767559; called by muse, mutect2, varscan2
- TOX2 | c.414C>T p.H138= (on ENST00000358131 / NM_001098798.2; = p.H87= on NM_032883.3) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs770775304, COSV57894416; called by muse, mutect2, varscan2
- TREM1 | c.357C>T p.P119= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV55149509; called by muse, mutect2, varscan2
- TRIM42 | c.2109G>A p.G703= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs918976843, COSV53881461; called by muse, varscan2
- TRPM5 | c.2550C>T p.I850= | Silent (SNP) | VAF 40/56 reads (71%) | catalogued as COSV50184167; called by muse, mutect2, varscan2
- USP19 | c.3697C>T p.L1233= | Silent (SNP) | VAF 41/54 reads (76%) | catalogued as COSV67351594; called by muse, mutect2, varscan2
- VPREB1 | c.285G>A p.R95= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV56426237; called by muse, mutect2, varscan2
- ZFHX3 | c.2911C>T p.L971= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs772902362, COSV51733238; called by muse, mutect2, varscan2
- ZNF107 | c.1461G>A p.K487= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV61330569, COSV61331577; called by muse, mutect2, varscan2
- ZNF257 | c.12G>C p.L4= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV71311348; called by muse, mutect2, varscan2
- ZNF257 | c.1191G>A p.E397= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV71306205, COSV71311359; called by muse, mutect2, varscan2
- ZNF415 | c.288T>C p.F96= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV54704565; called by muse, mutect2, varscan2
- ZNF746 | c.1230C>T p.A410= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV61408716; called by muse, mutect2, varscan2
- AC133065.1 | n.439-1301C>T | Intron (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- IGHG1 | chr14:105737787 C>T | 3'Flank (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- IGHV1-12 | n.79G>T | RNA (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- MIR520G | n.52A>T | RNA (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- MOG | c.593-89G>A | Intron (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100971889; called by muse, mutect2, varscan2
- SYT1 | c.929-24796C>T | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as rs756466109, COSV99695872; called by muse, varscan2
- SYTL2 | c.1459+2528T>C | Intron (SNP) | VAF 23/55 reads (42%) | catalogued as rs769492925, COSV100314384; called by muse, mutect2, varscan2
